Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7874, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7874-01A (Primary Tumor).

Microscopic

Sections demonstrate an anaplastic oligodendroglioma characterized by a proliferation of atypical glial cells arranged in sheets and nests. The tumor cells exhibit round nuclei, prominent perinuclear halos and a paucity of fibrillary processes. They exhibit mild to moderate nuclear atypia. Numerous microgemistocytes are also present. There is prominent microvascular proliferation as well as microfoci of necrosis. Numerous apoptotic cells as well as mitotic figures are seen at up to 11 per 10 high power fields. The adjacent brain parenchyma is both edematous and gliotic and exhibits individual infiltrating tumor cells. Scattered microcalcifications are also identified. These histologic features are consistent with high grade oligodendroglioma.

Addendum

The MIB-1 labeling index ranges up to 15.6% in the most proliferative regions of tumor, consistent with a high grade glioma

Diagnosis

Anaplastic oligodendroglioma grade III

Source: NCI Genomic Data Commons file 12ce1d31-debb-4e9f-b00c-27de1748964a (TCGA-HT-7874.DEE7AAF7-0E9A-454B-A9AA-C31EAED09359.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).